Somatic mutation profile of tumor specimen TARGET-30-PATWGR-01A (aliquot TARGET-30-PATWGR-01A-01D) from TARGET case TARGET-30-PATWGR, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.8 years (1,039 days).
Specimen TARGET-30-PATWGR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 935294ab-df3b-4da7-92ee-a6235558973e.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATWGR-10A (Blood Derived Normal), aliquot TARGET-30-PATWGR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/520bde38-e124-43d1-b017-15a66fb284fc

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK | c.4580G>T p.G1527V | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- AR | c.*5174T>A | 3'UTR (SNP) | VAF 55/81 reads (68%) | catalogued as COSV65963633; called by muse, mutect2, varscan2
